Gene-level copy-number profile of tumor specimen TARGET-40-0A4I4E-01A from TARGET case TARGET-40-0A4I4E, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.4 years (5,978 days).
Specimen TARGET-40-0A4I4E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.6ec5a99a-e376-5ef0-8535-f1f6fc0819cf.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I4E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate.
https://portal.gdc.cancer.gov/files/1710e61a-a3c0-403f-988f-b186f670ed0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 269; copy number 1: 10,273; copy number 2: 34,640; copy number 3: 11,558; copy number 4: 1,406; copy number 5: 1,113; copy number 6: 179; copy number 7: 70; copy number 8: 220; copy number 9: 162; copy number 10: 80; copy number 11: 116; copy number 12: 166; copy number 14: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,869 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,568,527, 2 genes, copy number 5: UGT2B29P, UGT2B17.
- chr7:64,307,459–71,713,600, 143 genes, copy number 5–6 (broad region; genes not listed).
- chr8:32,911,493–40,402,010, 141 genes, copy number 5–12 (broad region; genes not listed).
- chr8:57,126,655–65,184,210, 111 genes, copy number 5 (broad region; genes not listed).
- chr8:66,432,486–122,127,184, 793 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:63,558,913–63,795,718, 4 genes, copy number 5 (within-gene range 2–5): DPY19L2, AC084357.2, AC027667.1, AC084357.3.
- chr13:19,552,571–19,675,884, 6 genes, copy number 5: MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2.
- chr17:9,910,606–13,018,065, 57 genes, copy number 5–11 (within-gene range 1–11): GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2.
- chr17:13,299,184–22,221,605, 389 genes, copy number 8–12 (broad region; genes not listed).
- chr17:36,210,924–36,543,435, 15 genes, copy number 5 (within-gene range 2–5): CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19.
- chr19:12,064,731–13,633,025, 100 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr21:14,774,301–23,281,909, 108 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,848. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
